Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A3W5, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A3W5-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

E

E

* Final Report *

ICD-O-3
carcinoma, lobular, infiltrating
8520/3

Result type: Surgical Pathology Report
Result date:
Result status: Signed
Result title: Surgical Pathology Report
Performed by:
Verified by:
Encounter info:

Site: breast, NOS
CSO.9 5-1-12
PD

* Final Report *

Clinical History

Right breast pleomorphic ILC triple positive on prior core at 9:00 position
; E-cadherin immunostain was negative on core

Specimen

- #1 Sentinel node #1, right axilla, hot and blue
- #2 Sentinel node #2, right axilla, hot and blue
- #3 Sentinel node #3, right axilla, hot and blue
- #4 Right breast lumpectomy stitch, single long/cranial, double short/medial
- #5 Right breast mass, cranial margin
- #6 Right breast mass, medial margin
- #7 Right breast mass, caudal margin
- #8 Right breast mass, lateral margin
- #9 Right breast mass, deep margin

Gross Examination

#1 Received fresh labeled sentinel node #1, right axilla, hot and blue is a 1.2 x 0.6 x 0.5 cm portion of tan-yellow fibroadipose tissue. Within the tissue is a 0.5 x 0.4 x 0.4 cm lymph node candidate. The candidate is bisected along its longitudinal axis, and one alcohol-fixed touch preparation as well as one scrape preparation are prepared from the cut surface. The candidate is entirely submitted as two sections in one cassette.

#2 Received fresh labeled sentinel node #2, hot and blue, right axilla is a 1.2 x 0.5 x 0.4 cm portion of tan-yellow fibroadipose tissue. Within the tissue is a 0.4 x 0.4 x 0.4 cm lymph node candidate. The candidate is bisected along its longitudinal axis, and one alcohol-fixed touch preparation as well as one scrape preparation are prepared from the cut surface. The candidate is entirely submitted as two sections in one cassette.

#3 Received fresh labeled sentinel node #3, right axilla, hot and blue is a 1.3

Printed by:
Printed on:

Page 1 of 4
(Continued)

RNA Discrepancy		
Not Synchronous Primary		

[page 2 of 4]
Surgical Pathology Report

E

E

* Final Report *

x 0.7 x 0.6 cm portion of tan-yellow fibroadipose tissue. Within the tissue is a 0.8 x 0.5 x 0.4 cm lymph node candidate. The candidate is bisected along its longitudinal axis, and one alcohol-fixed touch preparation as well as one scrape preparation are prepared from the cut surface. The candidate is entirely submitted as two sections in one cassette.

#4 Received fresh labeled right breast lumpectomy, stitch single long cranial, double short medial, is a 5.8 cm (cranial to caudal) x 4.2 cm (medial to lateral) x 2.0 cm (superficial to deep) portion of fibroadipose tissue, oriented as stated above. The superficial margin is inked blue and the deep margin is inked black. Sectioning demonstrates a stellate, moderately well circumscribed 2.6 x 2.2 x 1.0 cm white, indurated mass. Within the mass is a 0.4 cm in greatest dimension hemorrhagic biopsy cavity. The mass demonstrates the following measurements of the margins: medial-0.3 cm, lateral-0.9 cm, superficial-0.9 cm, deep-1.0 cm, caudal-1.1 cm and cranial-1.6 cm. The remainder of the parenchyma is composed entirely of lobulated adipose tissue. There are no additional discrete mass lesions or nodules identified. Seven sections are submitted in seven: "A-G". Block summary: "A", medial perpendicular; "B", lateral perpendicular; "C", superficial and deep (differentially inked) perpendicular; "D", superficial perpendicular; "E", deep perpendicular; "F", caudal shave; "G", cranial shave.

Representative fresh tumor and normal tissue provided to () and the

#5 Labeled right breast mass, cranial margin, is a 5.0 x 3.2 x up to 1.3 cm cup-shaped portion of tan yellow fibroadipose tissue, oriented with a cranial map marker on one surface. The cranial margin is inked black and tangential sections are taken. The remaining tissue is serially sectioned to demonstrate no gross focal mass or lesion. Six representative sections are submitted in five: "A-E". Block summary: "A-D", entire cranial margin, tangential; "E", perpendicular sections through the remaining tissue.

#6 Labeled right breast mass, medial margin, is a 3.0 x 3.0 x up to 1.0 cm cup-shaped portion of tan yellow fibroadipose tissue, oriented with a medial map marker on one surface. The medial margin is inked black. The tissue is serially sectioned to demonstrate no gross focal mass or lesion. The tissue is entirely submitted as nine perpendicular sections in six: "A-F".

#7 Labeled right breast mass, caudal margin, is a 3.0 x 2.5 x up to 0.8 cm cup-shaped portion of tan yellow fibroadipose tissue, oriented with a caudal map marker on one surface. The caudal margin is inked black. The tissue is serially sectioned to demonstrate no gross focal mass or lesion. The tissue is entirely submitted as eight perpendicular sections in five: "A-E".

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Surgical Pathology Report

* Final Report *

#8 Labeled right breast mass, lateral margin, is a 3.3 x 2.3 x up to 0.9 cm cup-shaped portion of tan yellow fibroadipose tissue, oriented with a lateral map marker on one surface. The lateral margin is inked black. The tissue is serially sectioned to demonstrate no gross focal mass or lesion. The tissue is entirely submitted as eight perpendicular sections in four: "A-D".

#9 Labeled right breast mass, deep margin, is a 5.0 x 3.2 x up to 1.6 cm cup-shaped portion of tan yellow fibroadipose tissue, oriented with a deep map marker on one surface. The deep margin is inked black, and tangential sections are taken. The remaining tissue is serially sectioned to demonstrate no gross focal mass or lesion. Seven representative sections are submitted in five: "A-E". Block summary: "A-D", entire deep margin, tangential; "E", perpendicular sections through the remaining tissue.

OR Consultation

#1 SENTINEL NODE #1 RIGHT AXILLA (1 LN, 1 TP, 1 SCRAPE): NEGATIVE (0/1).
#2 SENTINEL NODE #2 RIGHT AXILLA (1 LN, 1 TP, 1 SCRAPE): NEGATIVE (0/1).
#3 SENTINEL NODE #3 RIGHT AXILLA (1 LN, 1 TP, 1 SCRAPE): NEGATIVE (0/1).
#1-#3 REPORTED TO DR. AT ON

Signature Line

Signed by:
ELECTRONIC SIGNATURE

Microscopic Examination

#1-#9 Microscopic examination performed. Immunostain for pancytokeratin is evaluated on all blocks in parts 1-3 and show no metastatic carcinoma. The final medial margin is positive in block 6F (Dr.

Comment

The pleomorphic LCIS noted at the final medial margin is remote from the main tumor mass and likely represents an incidental finding.

Final Diagnosis

#1 SENTINEL LYMPH NODE #1, RIGHT AXILLA, EXCISION: NEGATIVE (0/1).
#2 SENTINEL LYMPH NODE #2, RIGHT AXILLA, EXCISION: NEGATIVE (0/1).
#3 SENTINEL LYMPH NODE #3, RIGHT AXILLA, EXCISION: NEGATIVE (0/1).

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
Surgical Pathology Report

E

III

* Final Report *

- #4 BREAST MASS, RIGHT AT 9:00, EXCISION:
INVASIVE LOBULAR CARCINOMA, PLEOMORPHIC TYPE, HIGH GRADE.
TUBULE FORMATION: MINIMAL (SCORE 3).
PLEOMORPHISM: MARKED (SCORE 3).
MITOTIC COUNT: MODERATE (SCORE 2).
TOTAL NOTTINGHAM SCORE: 8 OF 9 (GRADE III).
SIZE OF TUMOR: 2.6 CM OF INVASIVE CARCINOMA.
PERCENT OF IN SITU CARCINOMA: 1-2% (PLEOMORPHIC LCIS).
STATUS OF BREAST TISSUE AWAY FROM LESION: BENIGN.
LOCAL LYMPHATIC SPACE STATUS: NEGATIVE.
DERMAL LYMPHATIC SPACE STATUS: N/A.
SURGICAL MARGIN STATUS:
SUPERFICIAL: NEGATIVE (0.4 CM).
DEEP: NEGATIVE (0.5 CM).
MEDIAL: NEGATIVE (0.7 CM).
LATERAL: NEGATIVE (0.5 CM).
CRANIAL: NEGATIVE.
CAUDAL: POSITIVE FOR PLEOMORPHIC LCIS.
STATUS OF MICROCALCIFICATIONS: ABSENT.
ESTROGEN RECEPTOR ASSAY: POSITIVE ON PRIOR CORE (3+, 50%).
PROGESTERONE RECEPTOR ASSAY: POSITIVE ON PRIOR CORE (3+, 30%).
HERCEPT: POSITIVE ON PRIOR CORE (IHC SCORE 3+, FISH POSITIVE).
- #5 CRANIAL MARGIN, RIGHT BREAST: NEGATIVE.
- #6 MEDIAL MARGIN, RIGHT BREAST: FOCAL PLEOMORPHIC LCIS (0.4 CM).
FINAL MARGIN IS POSITIVE OVER A LENGTH OF 0.2 CM.
- #7 CAUDAL MARGIN, RIGHT BREAST: FOCAL PLEOMORPHIC LCIS (0.1 CM).
FINAL MARGIN IS NEGATIVE (0.5 CM).
- #8 LATERAL MARGIN, RIGHT BREAST: FOCAL PLEOMORPHIC LCIS (0.3 CM).
FINAL MARGIN IS NEGATIVE (0.6 CM).
- #9 DEEP MARGIN, RIGHT BREAST: NEGATIVE.
- PATHOLOGIC STAGE: pT2 pN0(sn)(i-).

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file be7ad45d-05de-4cc8-83d2-3bebaf45d6bd (TCGA-AC-A3W5.CA0CD57E-DA92-463E-A004-D554825A22D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).